Somatic mutation profile of tumor specimen TCGA-25-2397-01A (aliquot TCGA-25-2397-01A-01W-0799-08) from TCGA case TCGA-25-2397, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.1 years (21,581 days).
Specimen TCGA-25-2397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55187da7-f7da-43d5-b363-d8172dd3d8af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2397-10A (Blood Derived Normal), aliquot TCGA-25-2397-10A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79dbab7f-d522-4261-865b-375f064a07e8

The open-access MAF lists 76 somatic variants for this specimen: 63 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 11, Nonsense Mutation 5, Frame Shift Del 4, RNA 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 373/408 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4522A>C p.T1508P | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs80075294; called by muse, mutect2
- ADAMTS4 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 51/124 reads (41%) | catalogued as COSV100917846; called by muse, mutect2, varscan2
- ASPM | c.9328C>G p.H3110D | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV54133282, COSV99660908; called by muse, mutect2, varscan2
- ATP8A2 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV54969711; called by muse, mutect2
- BCL2L14 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 139/245 reads (57%) | catalogued as COSV99845229; called by muse, mutect2, varscan2
- CCDC146 | c.2699A>G p.N900S | Missense Mutation (SNP) | VAF 172/348 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs372248491; called by muse, mutect2, varscan2
- CD36 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs756489185, COSV59214502, COSV59216834; called by muse, mutect2, varscan2
- CIT | c.2790T>A p.D930E | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.978); catalogued as COSV99950588; called by muse, mutect2, varscan2
- COL19A1 | c.3196G>C p.G1066R | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100507139, COSV59564466; called by muse, mutect2, varscan2
- DNAJA1 | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV100438598; called by muse, mutect2, varscan2
- FAM90A1 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100274464; called by muse, mutect2, varscan2
- FANCM | c.2593C>G p.Q865E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs776830147, COSV99951485; called by muse, mutect2, varscan2
- GRIK1 | c.437T>C p.F146S | Missense Mutation (SNP) | VAF 401/970 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV100517591; called by muse, mutect2, varscan2
- HINFP | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.04); catalogued as rs761842414, COSV100640876; called by muse, mutect2, varscan2
- IGSF10 | c.4114A>T p.T1372S | Missense Mutation (SNP) | VAF 258/598 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99192204; called by muse, mutect2, varscan2
- KPRP | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 240/581 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100908640; called by muse, mutect2, varscan2
- KY | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as rs750351662, COSV71018091; called by muse, mutect2, varscan2
- LARS2 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99648181; called by muse, mutect2, varscan2
- LCP2 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as COSV50453940, COSV50454264; called by muse, mutect2, varscan2
- MASP1 | c.391T>A p.F131I | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99397559; called by muse, mutect2, varscan2
- MED10 | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.935); catalogued as COSV99740379; called by muse, mutect2, varscan2
- MIS18A | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV99267115; called by muse, mutect2, varscan2
- MPHOSPH10 | c.113A>T p.K38M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV99731244; called by muse, mutect2, varscan2
- MRS2 | c.607A>C p.K203Q | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.517); catalogued as COSV99219085; called by muse, mutect2, varscan2
- MTCL1 | c.3293G>C p.C1098S (on ENST00000306329 / NM_001378206.1; = p.C779S on NM_015210.4) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100095361; called by muse, mutect2, varscan2
- MTHFR | c.254C>G p.A85G | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100412138; called by muse, mutect2, varscan2
- MYO1D | c.2286G>A p.W762* | Nonsense Mutation (SNP) | VAF 316/377 reads (84%) | catalogued as rs745367684, COSV59016889; called by muse, mutect2, varscan2
- NECTIN1 | c.1033C>A p.H345N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99872531; called by muse, mutect2, varscan2
- NME8 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200863038, COSV52246730, COSV99553828; called by muse, mutect2, varscan2
- OR8D4 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 116/465 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100361903; called by muse, mutect2, varscan2
- OTOL1 | c.1047G>C p.L349F | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100020176; called by muse, mutect2, varscan2
- PAM | c.2398A>G p.T800A | Missense Mutation (SNP) | VAF 398/479 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99173720; called by muse, mutect2, varscan2
- PLXNB1 | c.851C>A p.S284Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.834); catalogued as COSV99603277; called by muse, mutect2, varscan2
- RNF41 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 113/153 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100560310; called by muse, mutect2, varscan2
- RYR1 | c.11615A>T p.K3872M | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616637; called by muse, mutect2, varscan2
- SLC11A1 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV99262370; called by muse, mutect2, varscan2
- SLC25A25 | c.727T>A p.W243R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100895365; called by muse, mutect2, varscan2
- STYXL2 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV99609701; called by muse, mutect2, varscan2
- TLE4 | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 117/252 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751862890, COSV54627568, COSV54629250; called by muse, mutect2, varscan2
- TNIK | c.963T>G p.Y321* | Nonsense Mutation (SNP) | VAF 84/174 reads (48%) | catalogued as COSV99458966; called by muse, mutect2, varscan2
- TOX | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV100789299; called by muse, varscan2
- UBR1 | c.2794del p.A932Lfs*6 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as COSV51930802; called by mutect2, pindel, varscan2
- USP21 | c.409G>C p.A137P | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.278); catalogued as rs1013474720, COSV99237696; called by muse, mutect2, varscan2
- VIM | c.847A>G p.N283D | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99813281; called by muse, mutect2, varscan2
- VSIG1 | c.1001C>G p.P334R | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV99480435; called by muse, mutect2, varscan2
- ZDHHC16 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 104/111 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV100513051; called by muse, mutect2, varscan2
- ZNF445 | c.2906A>G p.Q969R | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs758174102, COSV101253863; called by muse, mutect2
- ZNF667 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99410833; called by muse, mutect2, varscan2
- ZNF80 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV100352105; called by muse, mutect2, varscan2
- ZSWIM2 | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99720422; called by muse, mutect2, varscan2
- ZSWIM8 | c.4691C>A p.S1564* (on ENST00000605216 / NM_001242487.2; = p.S1569* on NM_015037.3) | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as rs1244420077; called by muse, mutect2
- ARFGEF2 | c.5233T>C p.F1745L | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2
- FERMT2 | c.1933G>C p.V645L | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2
- GOLGA6A | c.1961_1962del p.Y654* | Frame Shift Del (DEL) | VAF 41/145 reads (28%) | called by mutect2, pindel, varscan2
- GSDMA | c.1019C>G p.T340R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ITPR1 | c.3139G>A p.E1047K (on ENST00000354582; = p.E1032K on NM_002222.7) | Missense Mutation (SNP) | VAF 44/1916 reads (2%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- KDM3A | c.3581_3585del p.E1194Afs*14 | Frame Shift Del (DEL) | VAF 58/155 reads (37%) | called by mutect2, pindel, varscan2
- LPIN3 | c.2274G>T p.Q758H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2
- MATN4 | c.1132_1135+13del p.X378_splice (on ENST00000372754; = p.X337_splice on NM_003833.4) | Splice Site (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- PTPN14 | c.654A>C p.E218D | Missense Mutation (SNP) | VAF 37/1018 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC7A6 | c.919-28_929del p.X307_splice | Splice Site (DEL) | VAF 264/763 reads (35%) | called by mutect2, pindel
- SYT3 | c.1181_1197del p.R394Pfs*16 | Frame Shift Del (DEL) | VAF 20/32 reads (63%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.561C>G p.L187= | Silent (SNP) | VAF 44/1260 reads (3%) | called by muse, mutect2
- CTRC | c.618T>C p.D206= | Silent (SNP) | VAF 74/252 reads (29%) | catalogued as COSV101036440; called by muse, mutect2, varscan2
- DNAH9 | c.3523T>C p.L1175= | Silent (SNP) | VAF 168/386 reads (44%) | catalogued as COSV52386149; called by muse, mutect2, varscan2
- FOXD4L4 | c.288T>A p.S96= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- GABRG2 | c.957C>A p.T319= (on ENST00000361925 / NM_001375343.1; = p.T279= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 308/1852 reads (17%) | catalogued as COSV62716609; called by muse, mutect2, varscan2
- GRM4 | c.2244C>A p.I748= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV100946065, COSV65217310; called by muse, mutect2, varscan2
- LRFN5 | c.1086T>A p.P362= | Silent (SNP) | VAF 75/278 reads (27%) | catalogued as COSV99985014; called by muse, mutect2, varscan2
- PTPRU | c.4122G>A p.G1374= | Silent (SNP) | VAF 66/250 reads (26%) | catalogued as COSV100113507; called by muse, mutect2, varscan2
- RESF1 | c.4857C>T p.T1619= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs760637892, COSV100440528; called by muse, mutect2, varscan2
- RPTOR | c.3828C>T p.F1276= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- WSB1 | c.840A>C p.V280= | Silent (SNP) | VAF 183/316 reads (58%) | catalogued as COSV99286120; called by muse, mutect2, varscan2
- SSPOP | n.11771A>G | RNA (SNP) | VAF 20/23 reads (87%) | catalogued as rs1276668842, COSV100947873; called by muse, mutect2, varscan2
- UBTFL2 | n.739C>A | RNA (SNP) | VAF 64/159 reads (40%) | called by muse, mutect2, varscan2
